Somatic mutation profile of tumor specimen MMRF_1931_2_BM_CD138pos (aliquot MMRF_1931_2_BM_CD138pos_T1_KHS5U_L14847) from MMRF case MMRF_1931, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.6 years (26,526 days).
Specimen MMRF_1931_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f345dfdc-c1d8-42f6-a417-7c4f2de26810.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1931_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1931_1_PB_WBC_C2_KHS5U_L08115; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b331d0dd-488a-4787-b4fc-7e274dcb74ae

The open-access MAF lists 162 somatic variants for this specimen: 80 protein-altering or splice-affecting, 19 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, 3'UTR 34, Silent 19, Intron 13, 5'UTR 8, 3'Flank 4, Splice Site 4, Nonsense Mutation 4, RNA 3, Splice Region 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 70/285 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.1058G>A p.R353K | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1320161420; called by muse, mutect2, varscan2
- ADARB2 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs967357807, COSV101187113; called by muse, mutect2, varscan2
- ATRNL1 | c.1330A>G p.I444V | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372322547; called by muse, mutect2, varscan2
- CDK13 | c.3031C>T p.L1011F | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs1374725564, COSV51702708; called by muse, mutect2, varscan2
- CNGB3 | c.1514C>A p.T505K | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60691782; called by muse, mutect2, varscan2
- COMP | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV55875521; called by muse, mutect2, varscan2
- DGKA | c.1052G>T p.S351I | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV59387305; called by muse, mutect2, varscan2
- DHRS7C | c.847G>A p.A283T (on ENST00000330255 / NM_001220493.2; = p.A282T on NM_001105571.3) | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1308907842, COSV57652697; called by muse, mutect2, varscan2
- DYNC1H1 | c.13013A>G p.D4338G | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as rs768250649; called by muse, mutect2, varscan2
- ERBB3 | c.3926G>A p.R1309H | Missense Mutation (SNP) | VAF 85/230 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs747453114, COSV57256533; called by muse, mutect2, varscan2
- FRG2B | c.535G>C p.V179L | Missense Mutation (SNP) | VAF 114/500 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.12); catalogued as COSV71044032; called by muse, varscan2
- FURIN | c.1411G>A p.V471M | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs774572749, COSV51574651; called by muse, mutect2, varscan2
- GPR152 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV56888028; called by muse, mutect2, varscan2
- IGHJ1 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 20/25 reads (80%) | catalogued as rs1381030792; called by muse, varscan2
- IGHJ4 | c.40T>G p.S14A | Missense Mutation (SNP) | VAF 76/98 reads (78%) | PolyPhen benign (0.005); catalogued as rs537730557; called by muse, mutect2, varscan2
- IGHV2-70 | c.69G>C p.L23F | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569950662; called by muse, varscan2
- IGHV2-70 | c.62T>G p.V21G | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs182292946; called by muse, varscan2
- IGKV4-1 | c.182G>C p.W61S | Missense Mutation (SNP) | VAF 62/89 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778196241; called by muse, mutect2, varscan2
- IGLL5 | c.25G>C p.G9R | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); catalogued as rs763031578, COSV104440262; called by muse, mutect2, varscan2
- KCNC2 | c.1343G>T p.W448L | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs746501735, COSV54361296; called by muse, mutect2, varscan2
- LCOR | c.4006G>T p.D1336Y | Missense Mutation (SNP) | VAF 78/178 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as rs1290515397; called by muse, mutect2, varscan2
- MROH2A | c.1139-1G>A p.X380_splice | Splice Site (SNP) | VAF 83/172 reads (48%) | catalogued as rs991786126; called by muse, mutect2, varscan2
- NDST1 | c.1943G>A p.G648D | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV55790379; called by muse, mutect2, varscan2
- OR10G9 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs750707868, COSV100901659; called by muse, mutect2, varscan2
- PAN2 | c.3060G>T p.E1020D (on ENST00000425394 / NM_001127460.3; = p.E1016D on NM_014871.5) | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV56264315; called by muse, mutect2, varscan2
- PCDHA7 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 96/348 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.13); catalogued as COSV65348150; called by muse, mutect2, varscan2
- PRR33 | c.1428G>A p.W476* | Nonsense Mutation (SNP) | VAF 43/115 reads (37%) | catalogued as COSV61134401; called by muse, mutect2, varscan2
- PRSS36 | c.2148G>A p.W716* | Nonsense Mutation (SNP) | VAF 81/223 reads (36%) | catalogued as COSV51639674; called by muse, mutect2, varscan2
- RFC2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs142327554; called by muse, mutect2, varscan2
- SCN10A | c.4119G>A p.M1373I | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1559414943; called by muse, mutect2, varscan2
- SLIT3 | c.2328C>A p.H776Q | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV60602358; called by muse, mutect2, varscan2
- SNTG1 | c.392_394del p.E131del | In Frame Del (DEL) | VAF 15/59 reads (25%) | catalogued as rs758567440; called by pindel, varscan2
- SNX17 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.306); catalogued as rs201136377; called by muse, mutect2, varscan2
- SORL1 | c.5186G>A p.R1729H | Missense Mutation (SNP) | VAF 98/273 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs534646732, COSV52751649; called by muse, mutect2, varscan2
- STRN | c.1367A>C p.K456T | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55745858; called by muse, mutect2, varscan2
- UBE3C | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 93/272 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.41); catalogued as rs528939743; called by muse, mutect2, varscan2
- UHMK1 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778270680; called by muse, mutect2, varscan2
- UNK | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53142362; called by muse, mutect2, varscan2
- ABCA13 | c.8410A>G p.S2804G | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM32 | c.209dup p.L70Ffs*4 | Frame Shift Ins (INS) | VAF 7/64 reads (11%) | called by mutect2, pindel, varscan2
- ALG6 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C15orf39 | c.2920G>C p.E974Q | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CMTM1 | c.244C>T p.L82F (on ENST00000457188 / NM_181269.3; = p.L199F on NM_052999.4) | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.383); called by muse, varscan2
- COL12A1 | c.5524+2T>C p.X1842_splice | Splice Site (SNP) | VAF 29/69 reads (42%) | called by muse, mutect2, varscan2
- COL19A1 | c.2804G>T p.G935V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX42 | c.-16-1G>A | Splice Site (SNP) | VAF 45/178 reads (25%) | called by muse, mutect2
- DLG1 | c.2282A>G p.H761R (on ENST00000419354 / NM_001290983.1; = p.H783R on NM_004087.2) | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DSC2 | c.982A>G p.M328V | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, varscan2
- DSG4 | c.2620A>T p.N874Y | Missense Mutation (SNP) | VAF 114/327 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- EIF1AX | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FBXO46 | c.1532G>C p.G511A | Missense Mutation (SNP) | VAF 9/282 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- GRIK2 | c.2700G>T p.R900S | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- GUCY1A1 | c.613T>G p.F205V | Missense Mutation (SNP) | VAF 191/447 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGHV2-70D | c.204G>A p.W68* | Nonsense Mutation (SNP) | VAF 68/245 reads (28%) | called by muse, varscan2
- IGHV2-70D | c.166A>C p.S56R | Missense Mutation (SNP) | VAF 59/199 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.513); called by muse, varscan2
- IGKV5-2 | c.285T>G p.I95M | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- IGLV4-69 | c.50-2A>G p.X17_splice | Splice Site (SNP) | VAF 76/192 reads (40%) | called by muse, varscan2
- IGLV5-52 | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INSL4 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- KALRN | c.7711G>A p.A2571T (on ENST00000360013 / NM_001024660.4; = p.A874T on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KBTBD6 | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- MARK4 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MKRN3 | c.1208T>G p.F403C | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MUC4 | c.12625C>G p.L4209V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.821); called by muse, varscan2
- OPHN1 | c.396del p.K133Nfs*81 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- OR10S1 | c.201C>A p.H67Q | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SAMD1 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 73/449 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCARF1 | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 51/125 reads (41%) | called by muse, mutect2, varscan2
- SCN9A | c.3218A>G p.D1073G (on ENST00000303354; = p.D1062G on NM_002977.3) | Missense Mutation (SNP) | VAF 128/303 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLCO4C1 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2
- SLCO6A1 | c.1729A>C p.K577Q | Missense Mutation (SNP) | VAF 102/182 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SPHKAP | c.2969C>T p.T990I | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPTBN4 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST6GALNAC5 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 44/109 reads (40%) | PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TICAM1 | c.1623G>T p.R541S | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TICRR | c.3971C>T p.P1324L | Missense Mutation (SNP) | VAF 13/291 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2
- TSC1 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UQCRB | c.226T>G p.L76V | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- URGCP-MRPS24 | c.*22A>G | Splice Region (SNP) | VAF 45/119 reads (38%) | called by muse, mutect2, varscan2
- CCDC170 | c.1264C>A p.R422= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as COSV99498491; called by muse, mutect2, varscan2
- CNTNAP2 | c.642G>A p.L214= | Silent (SNP) | VAF 94/177 reads (53%) | called by muse, mutect2, varscan2
- DHCR24 | c.1320T>C p.Y440= | Silent (SNP) | VAF 72/169 reads (43%) | called by muse, mutect2, varscan2
- EDEM1 | c.132G>A p.Q44= | Silent (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- ERICH3 | c.2097G>A p.K699= | Silent (SNP) | VAF 111/255 reads (44%) | catalogued as rs752483212, COSV100445723; called by muse, mutect2, varscan2
- FAM131A | c.870G>A p.E290= (on ENST00000310585; = p.E321= on NM_144635.5) | Silent (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- FAM47A | c.1038G>T p.R346= | Silent (SNP) | VAF 12/145 reads (8%) | called by muse, mutect2
- FSIP2 | c.5880A>G p.T1960= | Silent (SNP) | VAF 67/174 reads (39%) | called by muse, mutect2, varscan2
- GRM6 | c.297C>T p.C99= | Silent (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2
- H1-2 | c.186G>T p.L62= | Silent (SNP) | VAF 68/170 reads (40%) | catalogued as COSV100642309, COSV59192116; called by muse, mutect2, varscan2
- IGHV2-70D | c.207T>A p.L69= | Silent (SNP) | VAF 56/250 reads (22%) | called by muse, varscan2
- MYH4 | c.4602G>A p.K1534= | Silent (SNP) | VAF 59/154 reads (38%) | called by muse, mutect2, varscan2
- NLGN1 | c.450C>T p.S150= | Silent (SNP) | VAF 37/190 reads (19%) | catalogued as rs140286287, COSV64324345; called by muse, mutect2, varscan2
- NLRC4 | c.2718C>T p.V906= | Silent (SNP) | VAF 59/194 reads (30%) | called by muse, mutect2, varscan2
- NPY4R2 | c.606C>T p.T202= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs1554989405; called by mutect2, varscan2
- NRXN3 | c.1449G>A p.S483= | Silent (SNP) | VAF 80/192 reads (42%) | catalogued as rs763322026; called by muse, mutect2, varscan2
- PHF14 | c.1473C>T p.F491= | Silent (SNP) | VAF 50/148 reads (34%) | catalogued as rs1458568278; called by muse, mutect2, varscan2
- RIPOR1 | c.123C>T p.F41= (on ENST00000379312 / NM_001193522.2; = p.F37= on NM_024519.4) | Silent (SNP) | VAF 30/110 reads (27%) | called by muse, varscan2
- STRADB | c.252A>C p.T84= | Silent (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- ACTL6A | c.*129A>T | 3'UTR (SNP) | VAF 34/188 reads (18%) | called by muse, mutect2, varscan2
- AFG1L | c.*1523T>G | 3'UTR (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- AGPAT1 | c.*85C>A | 3'UTR (SNP) | VAF 35/67 reads (52%) | catalogued as rs1315991833; called by muse, mutect2, varscan2
- AGPS | c.*1111T>C | 3'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2
- ALDH7A1 | c.*2183G>T | 3'UTR (SNP) | VAF 60/241 reads (25%) | called by muse, mutect2, varscan2
- ARL5B | c.*2705A>C | 3'UTR (SNP) | VAF 47/115 reads (41%) | called by muse, mutect2
- BMP3 | c.*1310C>T | 3'UTR (SNP) | VAF 5/66 reads (8%) | catalogued as rs1051437135; called by muse, mutect2
- CACNA1E | c.*5991del | 3'UTR (DEL) | VAF 44/74 reads (59%) | called by mutect2, varscan2
- CADM2 | chr3:86067079 T>C | 3'Flank (SNP) | VAF 46/105 reads (44%) | catalogued as rs535289836; called by muse, mutect2, varscan2
- CENPL | chr1:173799720 G>C | 3'Flank (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- CERS6 | c.*2732A>C | 3'UTR (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- COL5A2 | c.2391+100T>C | Intron (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- DDIT4L | c.-13A>G | 5'UTR (SNP) | VAF 82/295 reads (28%) | catalogued as rs756374820; called by muse, mutect2, varscan2
- DLX3 | c.*53C>T | 3'UTR (SNP) | VAF 60/157 reads (38%) | catalogued as rs1290770803; called by muse, mutect2, varscan2
- EGLN3 | c.*549C>T | 3'UTR (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- FHL1 | c.*633A>G | 3'UTR (SNP) | VAF 62/69 reads (90%) | catalogued as rs1223549636; called by muse, mutect2, varscan2
- FYN | c.345-100A>G | Intron (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- GALK2 | c.*923C>T | 3'UTR (SNP) | VAF 34/138 reads (25%) | catalogued as rs1191465956; called by muse, mutect2, varscan2
- GCSAML | c.*2336G>T | 3'UTR (SNP) | VAF 41/116 reads (35%) | called by muse, mutect2, varscan2
- GLT1D1 | c.*839G>A | 3'UTR (SNP) | VAF 72/145 reads (50%) | called by muse, mutect2, varscan2
- GMPR2 | c.207+624C>T | Intron (SNP) | VAF 18/186 reads (10%) | called by muse, mutect2
- GPD1L | c.*1356A>G | 3'UTR (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- HSPB3 | c.-62C>G | 5'UTR (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- IGHV6-1 | c.-48A>C | 5'UTR (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- ISOC1 | c.*389T>C | 3'UTR (SNP) | VAF 63/104 reads (61%) | called by muse, mutect2, varscan2
- KCNJ3 | c.*1712T>G | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- KLF7 | c.*5058G>A | 3'UTR (SNP) | VAF 20/70 reads (29%) | catalogued as rs1230380446; called by muse, mutect2, varscan2
- KMT2A | c.432+608dup | Intron (INS) | VAF 40/113 reads (35%) | called by mutect2, pindel, varscan2
- LYZL2 | c.*12A>T | 3'UTR (SNP) | VAF 151/443 reads (34%) | catalogued as rs1219183373; called by muse, mutect2, varscan2
- MBP | c.681+9C>T | Intron (SNP) | VAF 9/23 reads (39%) | catalogued as rs1301307981; called by muse, mutect2, varscan2
- MCAM | c.-5G>T | 5'UTR (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- MIPOL1 | c.1262+23339C>G | Intron (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100539627; called by muse, mutect2, varscan2
- MIR518E | n.4C>A | RNA (SNP) | VAF 51/154 reads (33%) | called by muse, mutect2, varscan2
- NEK7 | c.*1624C>A | 3'UTR (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- NFIB | c.*3523C>T | 3'UTR (SNP) | VAF 8/134 reads (6%) | catalogued as rs1016087576; called by muse, mutect2
- NKD1 | c.*1918G>T | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, varscan2
- NR1H4 | chr12:100499990 G>T | 5'Flank (SNP) | VAF 71/153 reads (46%) | called by muse, mutect2, varscan2
- NSFL1C | c.-809T>C | 5'UTR (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- OPRK1 | c.*3117C>T | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- OSGIN1 | n.2365T>C | RNA (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- PDGFD | c.125-36615G>T | Intron (SNP) | VAF 68/153 reads (44%) | catalogued as COSV100159818; called by muse, mutect2, varscan2
- POLK | c.2486-12T>A | Intron (SNP) | VAF 89/295 reads (30%) | called by muse, mutect2, varscan2
- PPM1B | chr2:44233267 A>T | 3'Flank (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- PRELID2 | c.510+542A>C | Intron (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- PRUNE2 | c.756+35190G>A | Intron (SNP) | VAF 72/438 reads (16%) | called by muse, mutect2, varscan2
- RGL1 | c.*2170T>A | 3'UTR (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2
- SEPTIN6 | chrX:119616475 C>T | 3'Flank (SNP) | VAF 84/110 reads (76%) | called by muse, mutect2, varscan2
- SGTA | c.*403G>A | 3'UTR (SNP) | VAF 45/83 reads (54%) | catalogued as rs973952049; called by muse, mutect2, varscan2
- SI | c.*442A>G | 3'UTR (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- SLC4A11 | c.1463+79G>A | Intron (SNP) | VAF 7/14 reads (50%) | catalogued as rs1452055557; called by muse, mutect2
- SNTB2 | c.*7612G>A | 3'UTR (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- SPATS2 | c.*79T>C | 3'UTR (SNP) | VAF 9/192 reads (5%) | called by muse, mutect2
- SQSTM1 | c.206-410A>C | Intron (SNP) | VAF 27/197 reads (14%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.-68C>T | 5'UTR (SNP) | VAF 29/75 reads (39%) | catalogued as rs1224547736, COSV100129763; called by muse, mutect2, varscan2
- ST8SIA4 | c.*396C>G | 3'UTR (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- STPG1 | c.737+143A>G | Intron (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- TMOD3 | c.*2954T>C | 3'UTR (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- TMX3 | c.-111C>A | 5'UTR (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- TRAT1 | c.*379G>A | 3'UTR (SNP) | VAF 18/55 reads (33%) | catalogued as rs540625575; called by muse, mutect2, varscan2
- TRMT2A | c.-251_-242del | 5'UTR (DEL) | VAF 29/123 reads (24%) | called by mutect2, pindel*
- TRPA1 | c.*8G>C | 3'UTR (SNP) | VAF 84/276 reads (30%) | called by muse, mutect2, varscan2
- VWFP1 | n.2746C>A | RNA (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- ZNF385D | c.*1981G>A | 3'UTR (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
